Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3374, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3374-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient
MRN
Date of Service
Performing Facility
Ordering Provider
Result Provider
Report Name

[REDACTED] Requested by: [REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

ACCESSION #: [REDACTED]

PROCEDURE DATE: [REDACTED]

==== SPECIMEN DESCRIPTION: =====

Right kidney

==== PRE-OPERATIVE DIAGNOSIS: =====

Right renal mass

==== POST-OPERATIVE DIAGNOSIS: =====

Same

==== CLINICAL INFORMATION: =====

Same

==== GROSS DESCRIPTION: =====

The specimen consists of a kidney with small amounts of attached perirenal fat. The specimen weighs 253 g. It measures 12.5 x 7.4 x 4.5 cm in greatest dimension. The capsule strips with ease. In the superior pole of the kidney, there is a bulging mass. The kidney is bisected revealing a relatively well circumscribed tumor mass which is yellow to grayish-brown in color with foci of hemorrhage and cyst formation. The tumor measures 5.0 x 3.6 x 4.0 cm in greatest dimension. The renal pelvis and ureter are unremarkable. The renal vessels appear to be widely patent. No tumor thrombi is identified grossly. Representative tissue is submitted in a total of eight cassettes.

==== MICROSCOPIC DESCRIPTION: =====

Sections from the renal mass show a clear cell carcinoma with some papillary features. The malignant cells are present in sheets and also show tubule and papillary formation. The cells show mild nuclear pleomorphism with some nuclear enlargement. Occasional nuclei have distinct nucleoli. The cells have moderate to abundant amounts of pale pink to clear cytoplasm. Some of the cells lining the papillary structures appear to contain hemosiderin pigment. The tumor shows several foci of calcification with the stroma appearing hyalinized. The tumor is well demarcated from the adjacent uninvolved renal tissue. The tumor does not extend to the capsule. There is a thin rim of atrophic renal tissue between the tumor and the capsule. No renal vein invasion is identified. The remaining renal parenchyma is unremarkable. Sections from the pelvis and ureter show no significant pathologic changes. The renal arteries show minimal intimal fibrosis.

==== FINAL DIAGNOSIS: =====

RIGHT RADICAL NEPHRECTOMY:

- RENAL CELL CARCINOMA, CLEAR CELL TYPE WITH CALCIFICATION AND FOCI OF

[page 2 of 2]
[REDACTED]

Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient
MRN
Date of Service
Performing Facility
Ordering Provider
Result Provider
Report Name

ted by: [REDACTED]

PAPILLARY CHANGE, CONFINED TO THE KIDNEY

CODE 1,6

SUMMARY:

PROCEDURE:

TUMOR LOCATION:

TUMOR SIZE:

Right radical nephrectomy

Upper pole

5.0 x 3.6 x 4.0 cm, tumor confined to the kidney

NUCLEAR GRADE:

II

PATHOLOGIC STAGING:

T1,NX,MX

MARGINS:

Not involved

ADRENAL GLAND:

Not identified

[REDACTED] M.D.

[REDACTED]
(Electronic Signature)

Source: NCI Genomic Data Commons file 8d532add-fc98-471a-94af-3b7549d9d426 (TCGA-A3-3374.9E5D1E2B-5C9B-45F4-A021-EB3B33D881AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).